TCGA case TCGA-HV-AA8X — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: National Cancer Center Korea. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16b38977-aea1-4c75-89ec-4fb551f652dd

Demographics
Sex at birth: female; Race: asian; Country of residence at enrollment: South Korea; Age at index: 75 years; Vital status: Dead; Days to death: 532 days (1.5 years); Cause of death source: Medical Record.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.1; Tissue or organ of origin: Body of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 75.7 years (27,662 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Sites of involvement: Pancreas Body; Tumor grade category: Three Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 11.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 45 days; Days to treatment end: 253 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Distal Pancreatectomy.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Specified parts of peritoneum. Age at diagnosis: 76.8 years (28,037 days); Days to diagnosis: 375 days (1.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (2 entries)
- Day 375 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 375 days (1.0 years); Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 532 days (1.5 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HV-AA8X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 10 mg.
  Slide TCGA-HV-AA8X-01A-01-TS1: Section location: Top; Percent tumor cells: 22; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 3; Percent stromal cells: 72; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HV-AA8X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HV-AA8X-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-HV-AA8X-11Z: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 1; Alcohol history documented: No; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Follow-up form: Treatment outcome first course: Stable Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Drug treatment: Pharmaceutical therapy drug name: Gemcitabine Injection; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 532 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 532 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 375 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HV-AA8X-01A-11D-A396-01): tumor purity 0.65, ploidy 1.93, whole-genome doublings 0.
